Gene-level copy-number profile of tumor specimen TCGA-ZG-A9L9-01A from TCGA case TCGA-ZG-A9L9, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.5 years (22,108 days).
Specimen TCGA-ZG-A9L9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.482b5a05-5689-421a-8ef6-4e83c190fbc8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9L9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e22a2310-391a-4905-ab14-a82d55fa0137

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,102; copy number 2: 8,747; copy number 3: 11,818; copy number 4: 30,499; copy number 5: 2,996; copy number 6: 2,803; copy number 7: 777; copy number 8: 183; copy number 9: 489; copy number 10: 15; copy number 12: 366; copy number 19: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9L9-01A-11D-A41J-01): tumor purity 0.6, ploidy 3.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 879 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:5,455,218–5,716,804, 5 genes, copy number 10: AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2.
- chr8:12,412,827–18,401,218, 102 genes, copy number 9 (broad region; genes not listed).
- chr8:18,720,905–18,774,918, 2 genes, copy number 9: AC100800.1, RPL35P6.
- chr8:29,333,064–34,874,633, 95 genes, copy number 9 (broad region; genes not listed).
- chr8:54,509,422–54,871,720, 1 gene, copy number 9 (within-gene range 2–9): RP1.
- chr8:54,696,398–54,697,127, 1 gene, copy number 9: AC090151.1.
- chr8:61,500,556–61,714,640, 1 gene, copy number 9 (within-gene range 2–9): ASPH.
- chr8:61,631,680–73,370,601, 180 genes, copy number 9–12 (broad region; genes not listed).
- chr8:73,879,046–97,865,485, 359 genes, copy number 12–19 (broad region; genes not listed).
- chr8:111,376,639–111,757,710, 1 gene, copy number 10 (within-gene range 6–10): LINC02237.
- chr8:111,621,458–113,436,939, 9 genes, copy number 10: H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2.
- chr8:113,950,886–113,950,998, 1 gene, copy number 12: Y_RNA.
- chr12:93,467,514–99,984,654, 122 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 803. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
